Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABEO, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABEO-TTP1-A (Primary Tumor).

[page 1 of 21]
SURGICAL PATHOLOGY REPORT

* Amended *

Patient Name:	[REDACTED]	Accession #:	[REDACTED]	
Med. Rec. #:	[REDACTED]	Client:	[REDACTED]	Taken: [REDACTED] +0
DOB:	[REDACTED]	Location:	[REDACTED]	Received: [REDACTED] +0
Gender:	F	Copy To:		Reported: [REDACTED] +5
Physician(s):	[REDACTED]			

Final Diagnosis

Part D: "Right transverse colon", resection-

1. Invasive adenocarcinoma with near total luminal obstruction(see tumor characteristics)
2. Area of ischemic-type perforation in mid-portion of specimen(proximal to tumor mass) with adjacent pericolic adhesions consistent with effects of obstructive colopathy
3. Vermiform appendix with mucinous cystadenoma(low grade mucinous neoplasm)

TUMOR CHARACTERISTICS

Histologic grade	Poorly differentiated(grade 3 of 4)
Depth of mural invasion	Invasive adenocarcinoma extends extensively through the muscularis propria (>5cm into the adjacent fat)
Lymphatic invasion	Prominently seen both within the bowel wall and in pericolic soft tissue
Extramural venous invasion	Present in pericolic soft tissue with focal thrombosis. Extramural perineural invasion is also noted.
Lymph nodes	
Number positive/total number	At least 13 of 60 pericolic lymph nodes in this specimen positive for metastatic adenocarcinoma(13/60). See also parts A and C below.
Extranodal extension	Present, extensive; Often difficult to distinguish what is replaced lymph node from pericolic soft tissue invasion. Numerous matted nodes. This makes the lymph node count somewhat arbitrary.
pTNM stage grouping	pT4N2Mx
Margins of resection, closest	
Proximal and distal	Free of tumor
Radial	Extensively positive
Additional Comments	The tumor demonstrates only focal small gland formation with scattered cells with cytoplasmic mucin. It is possible that this tumor could represent a microsatellite instability-high(MSI-H) type of colon carcinoma as poorly differentiated tumors are over-represented in this group vs. those with microsatellite stable carcinomas. This, however cannot be proved solely with histopathologic study.

SCANNED

[page 2 of 21]
SURGICAL PATHOLOGY REPORT

Modified [REDACTED] utilizing AJCC Cancer Staging Manual, 6th edition (2002) and CAP's Reporting on Cancer Specimens (2000)

Part A: "Mesentery"- Poorly differentiated adenocarcinoma focally in soft tissue. Definitive lymph node architecture not identified in this specimen.

Part C: "Mesentery"- One lymph node with extensive replacement by metastatic adenocarcinoma (1/1).

Part B: "Peritoneal foreign body"- Fat necrosis with calcification. Negative for malignancy.

*****AMENDMENT NOTE*****
+5

According to conversation with [REDACTED] on [REDACTED] the area of inflammation and necrosis in the middle of the bowel specimen which demonstrated sutures and was indicated in the Final diagnosis of Part D #2 as consistent with an area of perforation actually represents the site of the previously performed diverting colostomy. Therefore line 3 of the Part D specimen should read:

2. Mural necrosis with acute inflammation and pericolonic fibroinflammatory changes consistent with region of diverting colostomy.

Amendments

Amended: [REDACTED]

Reason: Additional comment

Previous Signout Date: [REDACTED] +5

Specimen(s) Submitted

A: Mesentery - F.S.

B: "Peritoneal" foreign body

C: Mesentery

D: Rt. transverse colon

Pre-operative Diagnosis

Obstructing colon tumor

Post-operative Diagnosis

Same

Gross Description

Part A is received in the fresh state labeled "mesentery." It consists of multiple tan fragments of firm soft tissue. The largest fragment is 2 x 1.5 x 1 cm. Two other fragments are identified which each are 1 cm in greatest dimension. A frozen section is performed. The remainder of the frozen tissue is submitted labeled "FS" and then the remainder of the entire specimen is submitted in 2 cassettes. [REDACTED]

SCANNED

[page 3 of 21]
SURGICAL PATHOLOGY REPORT

Part B is labeled "peroneal foreign body". It consists of two yellowish-brown ovoid firm nodules, they measure 1.1 x 1.0 x 0.4 cm. and 1.5 x 1.0 x 0.3 cm. Each is bivalved to reveal a tan greasy and slightly gritty cut surface. Submitted entire, 1 block for brief decalcification.

Part C is labeled "mesentery". It consists of an irregularly shaped pink nodule which appears to be incised 3.0 x 2.0 x 1.5 cm. Sectioning reveals a pink surface which is partially encapsulated, centrally soft and friable. The specimen is submitted entire, 2 blocks.

Part D is labeled "right transverse colon". It consists of a segment of bowel with abundant attached fibrofatty tissue. There is a portion of small bowel identified representing terminal ileum that measures 5 cm. in length and 3 cm. in diameter. The appendix is identified and measures 5.5 x 1.0 x 0.9 cm. The large bowel measures 41 cm. in length. Located 12 cm. from distal margin, there is a large tan mass identified in the soft tissue and the bowel is firm in this area. The attached soft tissue is pliable, in the region of small bowel cecum and ascending colon towards the mid portion of the specimen the soft tissue is markedly firm with numerous hemorrhagic and fibrous adhesions. The fat focally twists and distorts the bowel due to attachment by the described adhesions. The large bowel measures 8.5 cm. in diameter. Where the firm mass is identified on the serosal surface radial margin in this area is marked with ink. Centrally located where there are numerous adhesions, there is a suture line which 8.5 cm. in length. There is abundant plaque like purulent material adherent to the specimen in this region. In the mid portion of the specimen the suture line is open. External margin in this area is marked with black ink while the radial margin in the region of the mass is marked with blue ink. The wall in this area is thickened and ragged. Upon opening, mucosa of the ileum is pink in color, folds are not prominent. There are no discrete lesions grossly identified. Ileocecal valve is pink to red and supple. Upon opening the cecum, the mucosa is pink-tan and exhibits normal folds. There are no mass lesions identified. The appendiceal orifice is patent. The large bowel is opened, ascending colon distal to the ileocecal valve exhibits a pink mucosa without prominent folds. There are no discrete lesions identified in the interval from ileocecal valve to the sutured defect. Bowel wall is thickened in this region up to 1.0 cm. Adjacent to the sutured defect there is a polypoid nodular mass which measures 6.2 cm. in length. The periphery is pink and it is elevated in areas up to 1.0 cm. beyond the surrounding mucosa. Sections reveal a folded like pinching of the muscle creating the elevated defect within the lumen. Proceeding towards the distal mass, the lumen is >90% narrowed by an annular constricting mass that is located 14 cm. from the distal margin. The mass measures 3 cm. in length. The mass is centrally ulcerated and there is adherent yellowish-green exudate at the base of the lesion. Sections through the mass reveal that it grossly appears to extend to the inked radial margin. The underlying soft tissue is markedly firm. On sectioning, there are rounded structures within the soft tissue representing extension of the mass for a distance of 5.5 cm. In areas, the cut surface appears to be matted lymph nodes within directly involved fibrofatty soft tissue. Discrete lymph nodes cannot be definitively identified or quantitated within this soft mass lesion. Random sections from the mass are submitted, adjacent soft tissue and all attached soft tissue are removed and placed in Carnoy's for lymph node dissection. Additionally submitted within the container are two portions of yellow lobular fatty tissue measuring 5.5 x 2.5 x 1.0 cm. and 6.5 x 2.5 x 1.0 cm. They are placed in Carnoy's with other mesentery for lymph node dissection. There is also an irregularly shaped staple portion of mucosa measuring 4.0 x 1.0 x 0.3 cm. Representative portions are submitted as follows: 1. proximal margin; 2. distal margin; 3. appendix; 4. edge of stapled opening in mid portion of bowel; 5. random sections ileum; 6. ileocecal valve; 7. random sections cecum; 8. sections of proximal portion of ascending colon; 9-10. sections in the mid portion of the specimen with the pinched and folded bowel wall proximal to main mass; 11-14. random sections of the bowel to include inked margin and underlying soft tissue; 15. separately submitted mucosal ring.

Intraoperative Diagnosis

FS A: Positive for poorly differentiated carcinoma (probably poorly differentiated adenocarcinoma)

SCANNED

[page 4 of 21]
[REDACTED]

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Med. Rec. #: [REDACTED]

DOB: [REDACTED]

Gender: F

Physician(s): [REDACTED]

Accession #: [REDACTED]

Client: [REDACTED]

Location: [REDACTED]

Copy To: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

+64

+64

+65

Final Diagnosis

"Liver", CT guided core biopsy- Poorly differentiated adenocarcinoma consistent with metastasis from patient's known colon primary(prior colon slides reviewed. [REDACTED]

Results called to [REDACTED] +64

Specimen(s) Submitted

Liver lesions on CT & MR

History

Hx. colon CA

Gross Description

The specimen is received in formalin labeled "liver biopsy". It consists of three tan and orange elongated fragments of soft tissue measuring 2.0 x 0.3 x 0.3 cm. Entire, 1 cassette. [REDACTED]

[REDACTED]

SCANNED

[page 5 of 21]
Previous Goto Radiology Transcription Cardiology Lab Pathology

Patient

Result Navigation 8 of 21

[1](#) [2](#) [3](#) [4](#) [5](#) [6](#) [7](#) [8](#) [9](#) [10](#) [11](#) [12](#) [13](#) [14](#) [15](#) [16](#) [17](#) [18](#) [19](#) [20](#) [21](#)

Final Report

(CCT 0040) PELVIS W/CONTRAST -6

COMMENTS:

Clinical Indication: Chronic epigastric cramping and loss of appetite.

Recent negative upper GI endoscopy.

Comparison: None.

Immediate and delayed postcontrast images of the abdomen and pelvis demonstrate a 7.3 x 6.4 cm minimally enhancing soft tissue mass with irregular lobulated margins and a few central ossifications in the left mid abdomen which abuts the superior of margin of the pancreatic tail without invading it and is associated with marked distention of the stomach, small bowel and particularly the cecum and transverse colon with the transition point at the splenic flexure with essentially complete collapse of the ascending colon and sigmoid distal to the mass. There is a small amount of fluid within the distended small bowel and proximal colon and there is moderate amount of stool the rectum. There is small amount of ascites in the pelvis. No bowel wall thickening or apparent mesenteric edema is seen. Therefore, these findings are most consistent with chronic partial colonic obstruction at the level of splenic flexure likely secondary to the large soft tissue mass in the distal transverse colon with or without volvulus. The appearance of the mass suggest a mucinous adenocarcinoma as a most likely etiology. Several nonenhancing nodular densities as seen separate from the mass posterior and healing. There is no evidence of free or loculated air or apparent inflammatory changes to suggest bowel ischemia or perforation.

The liver, gallbladder, pancreas, spleen, adrenals and kidneys are normal in size and appearance without focal lesion. Specifically there is no evidence of hepatic lesions to suggest a metastatic disease. No intrahepatic or extrahepatic biliary dilatation, hydronephrosis or nephrolithiasis is seen. Normal renal function is seen bilaterally. Both ureters are patent. The bladder is somewhat distorted by distended loops of bowel but otherwise unremarkable.

IMPRESSION: A 7.3 x 6.4 cm minimally enhancing soft tissue mass in the region now for the splenic colonic flexure with secondary partial colonic obstruction, as above. Possible mesenteric lymphadenopathy is also seen,

[page 6 of 21]
however, there is no evidence of hepatic metastatic disease. Correlation with air enema or colonoscopy is recommended.

153.9

CPT CODE: 72193

(CCT 0010) ABDOMEN W/CONTRAST -6

COMMENTS:

Clinical Indication: Chronic epigastric cramping and loss of appetite.

Recent negative upper GI endoscopy.

Comparison: None.

Immediate and delayed postcontrast images of the abdomen and pelvis demonstrate a 7.3 x 6.4 cm minimally enhancing soft tissue mass with irregular lobulated margins and a few central ossifications in the left mid abdomen which abuts the superior of margin of the pancreatic tail without invading it and is associated with marked distention of the stomach, small bowel and particularly the cecum and transverse colon with the transition point at the splenic flexure with essentially complete collapse of the ascending colon and sigmoid distal to the mass. There is a small amount of fluid within the distended small bowel and proximal colon and there is moderate amount of stool the rectum. There is small amount of ascites in the pelvis. No bowel wall thickening or apparent mesenteric edema is seen. Therefore, these findings are most consistent with chronic partial colonic obstruction at the level of splenic flexure likely secondary to the large soft tissue mass in the distal transverse colon with or without volvulus. The appearance of the mass suggest a mucinous adenocarcinoma as a most likely etiology. Several nonenhancing nodular densities as seen separate from the mass posterior and healing. There is no evidence of free or loculated air or apparent inflammatory changes to suggest bowel ischemia or perforation.

The liver, gallbladder, pancreas, spleen, adrenals and kidneys are normal in size and appearance without focal lesion. Specifically there is no evidence of hepatic lesions to suggest a metastatic disease. No intrahepatic or extrahepatic biliary dilatation, hydronephrosis or nephrolithiasis is seen. Normal renal function is seen bilaterally. Both ureters are patent. The bladder is somewhat distorted by distended loops of bowel but otherwise unremarkable.

IMPRESSION: A 7.3 x 6.4 cm minimally enhancing soft tissue mass in the region now for the splenic colonic flexure with secondary partial colonic obstruction, as above. Possible mesenteric lymphadenopathy is also seen, however, there is no evidence of hepatic metastatic disease. Correlation with air enema or colonoscopy is recommended.

153.9

[page 7 of 21]
Dictated By:

Electronically Signed:

tab [REDACTED] -6

Transcribed By:

D:

[REDACTED] -6

T:

[REDACTED] -6

[page 8 of 21]
PATIENT NAME:
ADDRESS:

PHONE:
M. R. NO:
HOSP SVC:
ORDERING DR:
CLIN HISTORY:

COLON CANCER

DOB:
SEX:
LOCATION:
ORDER NO:
PT. CLASS:
ATTENDING DR:
PRIMARY CARE DR:
PT ADM NO:

AGE: 69Y

Final Report

(CCT 0011) ABDOMEN W/VO CONTRAST

+51

COMMENTS:

History: Colon cancer

+8

Findings: CT scan of the abdomen and pelvis was performed and compared with prior study dated [REDACTED] Images through the lung bases demonstrate no pleural effusions. There is a granuloma which is unchanged in the left base on image one. Calcification is better appreciated on the prior study. There is heterogeneous low attenuation on postcontrast images involving the liver. The noncontrast images demonstrate no evidence of fatty infiltration as the liver demonstrates a higher Hounsfield unit value compared with the spleen. Therefore, it is not completely possible to exclude metastatic disease given the low attenuation and heterogeneous enhancement. There may be faint ring-enhancing lesions in the right hepatic lobe on images 11 and 12 which measure approximately 5 mm and 11 mm. However, this may simply be secondary to heterogeneous perfusion although an MRI is recommended to exclude metastatic disease. There is definite evidence of metastatic disease which has worsened compared to the prior study.

Specifically, there is confluent bulky lymphadenopathy within the upper abdomen which is most pronounced in the peripancreatic and celiac axes. A more discrete component of the lymphadenopathy adjacent to the greater curvature of the stomach within the celiac axis on image 15 measures 3.0 x 2.7 cm and previously measured 1.3 x 1.8 cm. The previously described 1.4 cm low density lesion involving the body of the pancreas currently measures 2.2 x 2.3 cm on image 20 although this is only a portion of more confluent lymphadenopathy which measures approximately 3.5 x 2.6 cm on image 21. Smaller mesenteric as well as retroperitoneal lymph nodes are also noted and have worsened compared with the prior study.

There are postsurgical changes due to partial bowel resection. The spleen demonstrates heterogeneous enhancement although no discrete mass is visualized. There is slightly unchanged nodularity of the left adrenal gland which measures 1.9 cm. This may represent an adrenal adenoma or metastatic disease. The right adrenal gland is unremarkable. The right kidney is not rotated. Subcentimeter cyst in the upper pole left kidney is unchanged. Adjacent to the left kidney, there is a more prominent soft tissue density adjacent to the spleen suspicious for lymphadenopathy which measures 1.5 x 0.9 cm and previously measured 1.2 x 0.7 cm. The gallbladder is present and demonstrates slight wall enhancement which is actually less prominent compared to the prior study. There are postsurgical changes, which are less pronounced in the subcutaneous fat and involving the abdominal wall musculature and omentum. There is a 1.1 centimeter subcutaneous lymph node involving the midline within the pelvis on image 54 which is not demonstrated on the prior study. Bladder is grossly normal.

IMPRESSION: Overall, significant worsening of metastatic disease.

[page 9 of 21]
PATIENT NAME:
ADDRESS:

PHONE:
M. R. NO:
HOSP SVC:
ORDERING DR:
CLIN HISTORY:

COLON CA NOS

DOB:
SEX:
LOCATION:
ORDER NO:
PT. CLASS:
ATTENDING DR:
PRIMARY CARE DR:
PT ADM NO:

AGE: 69Y

Heterogeneous low attenuation involving the liver. The possibility of metastatic disease cannot be excluded. MRI of the liver is recommended for further evaluation if this would change clinical management.

Significant worsening of bulky lymphadenopathy within the upper abdomen with invasion of the pancreatic body.

154.0

(CCT 0040) PELVIS W/CONTRAST +51

COMMENTS:

History: Colon cancer

+8

Findings: CT scan of the abdomen and pelvis was performed and compared with prior study dated [REDACTED] images through the lung bases demonstrate no pleural effusions. There is a granuloma which is unchanged in the left base on image one. Calcification is better appreciated on the prior study. There is heterogeneous low attenuation on postcontrast images involving the liver. The noncontrast images demonstrate no evidence of fatty infiltration as the liver demonstrates a higher Hounsfield unit value compared with the spleen. Therefore, it is not completely possible to exclude metastatic disease given the low attenuation and heterogeneous enhancement. There may be faint ring-enhancing lesions in the right hepatic lobe on images 11 and 12 which measure approximately 5 mm and 11 mm. However, this may simply be secondary to heterogeneous perfusion although an MRI is recommended to exclude metastatic disease. There is definite evidence of metastatic disease which has worsened compared to the prior study.

Specifically, there is confluent bulky lymphadenopathy within the upper abdomen which is most pronounced in the peripancreatic and celiac axes. A more discrete component of the lymphadenopathy adjacent to the greater curvature of the stomach within the celiac axis on image 15 measures 3.0 x 2.7 cm and previously measured 1.3 x 1.8 cm. The previously described 1.4 cm low density lesion involving the body of the pancreas currently measures 2.2 x 2.3 cm on image 20 although this is only a portion of more confluent lymphadenopathy which measures approximately 3.5 x 2.6 cm on image 21. Smaller mesenteric as well as retroperitoneal lymph nodes are also noted and have worsened compared with the prior study.

There are postsurgical changes due to partial bowel resection. The spleen demonstrates heterogeneous enhancement although no discrete mass is visualized. There is slightly unchanged nodularity of the left adrenal gland which measures 1.9 cm. This may represent an adrenal adenoma or metastatic disease. The right adrenal gland is unremarkable. The right kidney is not rotated. Subcentimeter cyst in the upper pole left kidney is unchanged. Adjacent to the left kidney, there is a more prominent soft tissue density adjacent to the spleen suspicious for lymphadenopathy which measures 1.5 x 0.9 cm and previously measured 1.2 x 0.7 cm. The gallbladder is present and demonstrates slight wall enhancement which is actually less prominent

[page 10 of 21]
PATIENT NAME:
ADDRESS:

PHONE:
M. R. NO:
HOSP SVC:
ORDERING DR:
CLIN HISTORY:

COLON CA NOS

DOB:
SEX:
LOCATION:
ORDER NO:
PT. CLASS:
ATTENDING DR:
PRIMARY CARE DR:
PT ADM NO:

AGE: 69Y

F

compared to the prior study. There are postsurgical changes, which are less pronounced in the subcutaneous fat and involving the abdominal wall musculature and omentum. There is a 1.1 centimeter subcutaneous lymph node involving the midline within the pelvis on image 54 which is not demonstrated on the prior study. Bladder is grossly normal.

IMPRESSION: Overall, significant worsening of metastatic disease.

Heterogeneous low attenuation involving the liver. The possibility of metastatic disease cannot be excluded. MRI of the liver is recommended for further evaluation if this would change clinical management.

Significant worsening of bulky lymphadenopathy within the upper abdomen with invasion of the pancreatic body.

154.0

CPT CODE:

Dictated By:

Transcribed By:

Electronically Signed

+51

[page 11 of 21]
PATIENT NAME:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY: RECTOSIGMOID JUNCTION CA

DOB:

SEX:

LOCATION:

ORDER NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

AGE: 69Y

F

Final Report

(CMR 0029) ABDOMEN W/WO CONTRAST +56

COMMENTS:

Clinical Indication: Colon cancer

Comparison: The study is correlated with the CT examination performed on +51

Technique: Magnetic resonance imaging of the abdomen was performed at 1.5 T with particular attention to the liver. Coronal and transverse images were obtained prior to and following the intravenous infusion of gadolinium.

Findings: In the posterior segment of the right lobe of the liver, there are focal hyperintensities on heavily T2-weighted images which correlate with the suspected focal metastases seen on a CT examination. The more lateral lesion measures approximately 1.4 x 1.1 cm. The more medial lesion measures approximately 0.9 x 0.8 cm. There is probably a lesion posteriorly in the dome of the liver measuring approximately 1.4 cm in diameter. There is a likely lesion in the left lobe measuring 0.8 cm in diameter. On dynamic gadolinium-enhanced images, a tiny, 5 mm lesion in the dome of the liver is suspected. The dynamic, gadolinium and enhanced images suggest presence of several additional lesions smaller than 5 mm in diameter. The gallbladder is unremarkable. There is bulky celiac axis and peripancreatic lymphadenopathy representing metastatic disease in the abdomen. The spleen appears normal. There is a small cortical cyst of the left kidney.

IMPRESSION:

1. Multiple small focal liver lesions representing metastatic disease.
2. Bulky lymphadenopathy in the celiac axis and peripancreatic region.

Diagnosis: 154.0, 199.0

Printed:

Page 1 of 1

[page 12 of 21]
PATIENT NAME:
ADDRESS:

DOB:

AGE: 69Y

SEX:

F

LOCATION:

-

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY: SKINNEY NEEDLE BIOPSY

ORDER NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

Final Report

(CCT 0051) BIOSPY LIVER SKINNY NEEDLE +64

COMMENTS: Clinical History: Colon carcinoma. Now with right posterior liver lesions and retroperitoneal adenopathy.

Comments: Informed consent was obtained. Patient was placed on the CT examination table in supine position. Monitored conscious sedation was administered. Localization imaging was performed. On noncontrast CT imaging lesion in the poster aspect of the right hepatic lobe is clearly evident and was chosen for biopsy. Using sterile technique and local anesthesia a 17 gauge introducer needle was advanced to the periphery of the lesion under CT guidance. Subsequently, multiple 18 gauge core specimens of the region were obtained in coaxial fashion. Introducer was removed and repeat imaging performed. The showed no change in the appearance of the liver and no evidence of perihepatic bleeding. Patient tolerated procedure well. There were no complications.

IMPRESSION: Uneventful CT guided biopsy of low-density lesion in the posterior aspect of the right hepatic lobe in patient with known colon carcinoma.

Diagnosis: 154.0

Printed:

Page 1 of 1

[page 13 of 21]
REPORT OF ROENTGEN FINDINGS
DEPARTMENT OF RADIOLOGY

PATIENT NAME	DATE OF BIRTH	AGE	SEX	DEPARTMENT	MED. REC.	EXAM DATE
		69Y	F			
PATIENT LOCATION	TECHNIQUE					
	RADIOLOGY ONLY					
REQUESTING PHYSICIAN	EXAM					
(W CHEST)	TUMOR METABOLIC IMAG/PET					
Attending Physician:				(W CHEST)	Acc #:	

+76

Associated exams:

CPT4 Codes:

History:

PT'S
COLON CA /RESTAGING

This study is a imaging center study.

IMPRESSION:

1. FDG AVID MASS IN THE UPPER MID ABDOMEN AT THE SURGICAL ANASTAMOSIS SITE CONSISTENT WITH RECURRENT TUMOR.
2. HETEROGENOUS FDG ACTIVITY IN THE LIVER WITH MULTIPLE LOW ATTENUATION LESIONS ON CT, SOME OF WHICH DEMONSTRATE IRREGULAR BORDERS ON THE NON CONTRAST IMAGES. THERE ARE NO DISCRETE AREAS OF INCREASED ACTIVITY CORRESPONDING TO THE LIVER LESIONS, FINDINGS MAY BE ATTRIBUTABLE TO HEPATIC METASTASES OR HEPATIC CYSTS. ULTRASOUND RECOMENDED FOR FURTHER EVALUATION.

HISTORY: The patient has a history of colon cancer.

TECHNIQUE: Images were submitted for review from the PET/CT study performed at the imaging site of the on
Images were acquired from the base of the skull to the mid thighs. The reported blood glucose at the time of injection was 72. The reported FDG dose was 16.5 mCi of 18-F FDG. Axial, sagittal, and coronal PET reconstructions were interpreted with and without attenuation correction. Corresponding CT images were also acquired in a spiral fashion utilizing 5.0mm axial slices, reconstructed in axial, sagittal, and coronal planes, and reviewed alongside the PET images. The limited noncontrast CT images were used for attenuation correction of the PET images and anatomical correlation.

COMMENTS: PET images demonstrate a large nonuniform area of intense FDG within the mid upper abdomen. Its maximal SUV measures 6.8, in the average SUV measures 6.7. On the CT scan findings represent a tumor mass at the surgical anastomosis site.

[page 14 of 21]
REPORT OF ROENTGEN FINDINGS

DEPARTMENT OF RADIOLOGY

Page 2

PATIENT NAME	DATE OF BIRTH	AGE	SEX	DEPARTMENT	MED. REC.	EXAM DATE
		69Y	F			
PATIENT LOCATION	TECHNIQUE					
	RADIOLOGY ONLY					
REQUESTING PHYSICIAN	EXAM					
	TUMOR METABOLIC IMAG/PET					
Attending Physician:				Acc #:		

+76

There is heterogeneous radiotracer distribution within the liver on the PET images. CT images demonstrate multiple low attenuation areas with the liver with irregular borders. There are no areas of clearly increased FDG activity corresponding to the liver lesions, however the CT findings and fused PET findings may still be attributable to hepatic metastases. Ultrasound is recommended for further evaluation to dedifferentiate solid masses from cysts.

Remaining distribution of radiotracer is normal. The limited images of the body are otherwise unremarkable if further evaluation is required a dedicated contrast CT is recommended for further evaluation.

I certify that I have personally reviewed this examination, and agree with this report.

Approved by:

Transcribed on:
Last Edited on:
Finalized on:

+77

+78

+78

Copy to:

C O P Y

[page 15 of 21]
PATIENT NAME:
ADDRESS:

PHONE:
M. R. NO:
HOSP SVC:
ORDERING DR:
CLIN HISTORY:

RECTOSIGMOID JUNCTION CA

DOB:
SEX:

LOCATION:
ORDER NO:
PT. CLASS:
ATTENDING DR:
PRIMARY CARE DR:
PT ADM NO:

AGE: 69Y

F

Final Report

(CCT 0040) PELVIS W/CONTRAST +184

COMMENTS: 69-year-old female with history of colon cancer, status post surgical resection and chemotherapy.

Helical CT of the abdomen and pelvis was performed following the administration of oral and IV contrast material. Initial precontrast enhanced images of the upper abdomen were also obtained. Comparison is made to the previous exam from +51

Findings: The most dramatic change on the current exam is near complete resolution of the previously seen very bulky lymphadenopathy within the celiac axis and peripancreatic region. One of the more superiorly located lymph nodes located posterior to the antrum of the stomach now measures 1.4 x 1.6 cm on image 18, compared to 2.7 x 3.2 cm. In the peripancreatic region, just above some surgical clips, a lymph node now measures 1.4 x 1.8 cm, compared to 3.2 x 4.7 cm. There are small remaining nodular areas of soft tissue surrounding the pancreatic head and upper mesenteric roots, but these do not meet size criteria for lymphadenopathy at this time. The pancreas now appears normal. The small soft tissue nodule adjacent to the splenic hilum is fairly stable in size, now measuring 1.0 x 1.4 cm on image 18, compared to 1.0 x 1.7 cm.

The liver now has a more overall homogeneous appearance. However, there may be a few very tiny low attenuation hepatic lesions. These are seen on image numbers 11 (two lesions are seen on this image, one laterally in the posterior right lobe and the other just anterior to the IVC), image #14 laterally in the anterior right lobe. There is no biliary dilatation. The gallbladder is unremarkable.

The spleen is normal in size with no focal lesions identified. The adrenal glands are unremarkable. Again seen is a tiny cortical cyst arising laterally from the upper pole of the left kidney. The kidneys are otherwise unremarkable and there is no hydronephrosis.

The stomach and small bowel are normal in appearance with no evidence of bowel obstruction. There appears to be an enterocolic anastomosis within the mid right abdomen. Some diverticula of the sigmoid colon are identified, but evaluation of the remainder of the colon is somewhat limited given the poor opacification of those segments. No ascites or fluid collections are identified. There is no aortic aneurysm. There is no new retroperitoneal lymphadenopathy.

In the pelvis, the urinary bladder is not particularly well distended but is grossly normal. The uterus appears to be present but is somewhat indistinct. Ovaries are not discretely visualized. The previously described small lymph node within the midline, anterior of the subcutaneous tissues of the pelvis, has resolved. A small fat containing inguinal hernia is seen on the left. There is no inguinal lymphadenopathy.

In the lung bases, again seen is a tiny nodule anteriorly in the left base, which is stable. No pleural effusions or new

[page 16 of 21]
PATIENT NAME:
ADDRESS:

PHONE:
M. R. NO:
HOSP SVC:
ORDERING DR:
CLIN HISTORY:

RECTOSIGMOID JUNCTION CA

DOB:
SEX:
LOCATION:
ORDER NO:
PT. CLASS:
ATTENDING DR:
PRIMARY CARE DR:
PT ADM NO:

AGE: 69Y

F

pulmonary nodules are identified. There are no significant osseous abnormalities.

IMPRESSION:

1. Dramatic improvement in previously seen lymphadenopathy in the upper mesentery.
2. There now appear to be four tiny low attenuation hepatic lesions, which were not appreciated on the previous exam. These are nonspecific in appearance, but certainly are more concerning in a patient with history of malignancy. Continued followup is recommended.
3. There is a stable, nonspecific solitary pulmonary nodule.

154.0, 793.1

ICD9:

CPT CODE: 72193

(CCT 0011) ABDOMEN W/VO CONTRAST +184

COMMENTS: See report for pelvis CT performed on the same date.

IMPRESSION: See report for pelvis CT performed on the same date.

ICD9:

CPT CODE: +184
Dictated By: +184
Transcribed By: D: +184 T: +184

[page 17 of 21]
PATIENT NAME:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY: RECTOSIGMOID JUNCTION CA

DOB:

SEX:

LOCATION:

ACCESSION NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

AGE: 70Y

F

Final Report

(CCT 0010) CT ABD W/CONTRAST +383

COMMENTS: Clinical Indication: Rectosigmoid junction carcinoma. Followup.

+279
CT images were obtained through the chest, abdomen and pelvis utilizing oral and intravenous contrast administration. comparison is made to the previous study of +279. Again seen is a calcified granuloma at the left base on image 30. Slight atelectasis is now seen inferiorly in the lingula. No other significant pulmonary abnormalities and no pleural or pericardial effusions are seen. No mediastinal, hilar or axillary masses or adenopathy is seen. A calcified subcarinal lymph node is present. Again seen is a port in the right anterior chest wall. Mild cardiomegaly is present. There are mild atherosclerotic changes of the aorta.

Again seen are a few tiny low density lesions scattered throughout the liver. These appear stable and are too small to characterize. The spleen, pancreas, adrenal glands and right kidney demonstrate no significant abnormalities. A small cyst at the upper pole of the left kidney on image 53 is less well visualized than previously. A small low density lesion in the left kidney on image 59 appears stable and is too small to characterize. Postoperative changes in the right abdomen consistent with enterocolonic anastomosis are less well visualized due to the presence of oral contrast within the colon. The urinary bladder and uterus are grossly intact. No free fluid or bowel obstruction is seen. Mild diverticulosis is present. A 2.0 cm right inguinal node is present and previously measured 1.9 cm. No other evidence of adenopathy seen.

IMPRESSION: A 2.0 cm right inguinal lymph node most likely represents a benign finding. Small low density lesions in the liver and kidney appear stable. Mild diverticulosis is again seen.

154.0

ICD9:

(CCT 0025) CT CHEST (THORAX) W/CONTR +383

COMMENTS: Clinical Indication: Rectosigmoid junction carcinoma. Followup.

[page 18 of 21]
PATIENT NAME:
ADDRESS:

PHONE:
M. R. NO:
HOSP SVC:
ORDERING DR:
CLIN HISTORY:

RECTOSIGMOID JUNCTION CA

DOB:
SEX:
LOCATION:
ACCESSION NO:
PT. CLASS:
ATTENDING DR:
PRIMARY CARE DR:
PT ADM NO:

AGE: 70Y

F

+279

CT images were obtained through the chest, abdomen and pelvis utilizing oral and intravenous contrast administration. comparison is made to the previous study of [REDACTED] Again seen is a calcified granuloma at the left base on image 30. Slight atelectasis is now seen inferiorly in the lingula. No other significant pulmonary abnormalities and no pleural or pericardial effusions are seen. No mediastinal, hilar or axillary masses or adenopathy is seen. A calcified subcarinal lymph node is present. Again seen is a port in the right anterior chest wall. Mild cardiomegaly is present. There are mild atherosclerotic changes of the aorta.

Again seen are a few tiny low density lesions scattered throughout the liver. These appear stable and are too small to characterize. The spleen, pancreas, adrenal glands and right kidney demonstrate no significant abnormalities. A small cyst at the upper pole of the left kidney on image 53 is less well visualized than previously. A small low density lesion in the left kidney on image 59 appears stable and is too small to characterize. Postoperative changes in the right abdomen consistent with enterocolonic anastomosis are less well visualized due to the presence of oral contrast within the colon. The urinary bladder and uterus are grossly intact. No free fluid or bowel obstruction is seen. Mild diverticulosis is present. A 2.0 cm right inguinal node is present and previously measured 1.9 cm. No other evidence of adenopathy seen.

IMPRESSION: A 2.0 cm right inguinal lymph node most likely represents a benign finding. Small low density lesions in the liver and kidney appear stable. Mild diverticulosis is again seen.

154.0

ICD9:

CPT CODE:

(CCT 0040) CT PELVIS W/CONTRAST

+383

COMMENTS: Clinical Indication: Rectosigmoid junction carcinoma. Followup.

+279

CT images were obtained through the chest, abdomen and pelvis utilizing oral and intravenous contrast administration. comparison is made to the previous study of [REDACTED] Again seen is a calcified granuloma at the left base on image 30. Slight atelectasis is now seen inferiorly in the lingula. No other significant pulmonary abnormalities and no pleural or pericardial effusions are seen. No mediastinal, hilar or axillary masses or adenopathy is seen. A calcified subcarinal lymph node is present. Again seen is a port in the right anterior chest wall. Mild cardiomegaly is present. There are mild atherosclerotic changes of the aorta.

Again seen are a few tiny low density lesions scattered throughout the liver. These appear stable and are too small to characterize. The spleen, pancreas, adrenal glands and right kidney demonstrate no significant abnormalities. A small cyst at the upper pole of the left kidney on image 53 is less well visualized than previously. A small low density lesion in the left

Printed:

Page 2 of 3

[page 19 of 21]
PATIENT NAME:

ADDRESS:

PHONE:

M. R. NO:

HOSP SVC:

ORDERING DR:

CLIN HISTORY: RECTOSIGMOID JUNCTION CA

DOB:

SEX:

LOCATION:

ACCESSION NO:

PT. CLASS:

ATTENDING DR:

PRIMARY CARE DR:

PT ADM NO:

AGE: 70Y

F

kidney on image 59 appears stable and is too small to characterize. Postoperative changes in the right abdomen consistent with enterocolonic anastomosis are less well visualized due to the presence of oral contrast within the colon. The urinary bladder and uterus are grossly intact. No free fluid or bowel obstruction is seen. Mild diverticulosis is present. A 2.0 cm right inguinal node is present and previously measured 1.9 cm. No other evidence of adenopathy seen.

IMPRESSION: A 2.0 cm right inguinal lymph node most likely represents a benign finding. Small low density lesions in the liver and kidney appear stable. Mild diverticulosis is again seen.

154.0

ICD9:

CPT CODE:

Dictated By:

Transcribed By:

D:

+383

Electronically Signed

T:

+383

+383

Printed:

Page 3 of 3

[page 20 of 21]
CT CHEST ABD PEL W (OS) Results Report

Pt Name: [REDACTED]
Pt ID: [REDACTED]
DOB: [REDACTED]
Adm DTime: [REDACTED] +3296
Nurs Sta: [REDACTED]
Dx: [REDACTED]
Alerg: No Known Drug Allergies

MRN: [REDACTED]
Acct No: [REDACTED]
Age/Sex: 79Y/F
Atn Dr: [REDACTED]
Rm & Bed: [REDACTED]

Order Name: [REDACTED]
Result Name: CT CHEST ABD PEL W (OS)

Observation Dtime: [REDACTED] +3913
Result Status: Final Result

FINAL REPORT

CT CHEST ABD PEL W (OS/NON) [REDACTED] +3913

COMMENTS: STUDY: CT of the CHEST and ABDOMEN and PELVIS after the uneventful intravenous administration of 100 cc of Omnipaque 350. Oral contrast was also used.

INDICATION: Metastatic colon cancer

COMPARED WITH: CT the chest, abdomen, pelvis performed on [REDACTED] +3556
CHEST

LUNG AND AIRWAYS: The airways appear widely patent throughout. There is minimal biapical lung scarring. There is minimal posterior and bibasilar dependent atelectasis. There is mild subsegmental atelectasis seen within the lower lobes. Minimal right middle lobe and lingular atelectasis. Small lingular calcified granuloma. No new lung nodule or mass.

PLEURA: No pleural effusion or pneumothorax.

VESSELS: Atherosclerotic changes in the aorta and coronary arteries. There is prominence of the main pulmonary arterial trunk possibly related to pulmonary hypertension.

HEART: Top normal in size. No pericardial effusion.

MEDIASTINUM AND HILA: A few small subcentimeter mediastinal lymph nodes, some of which are partially calcified, likely related to prior granulomatous disease. No lymphadenopathy by size criteria.

CHEST WALL AND LOWER NECK: No significant supraclavicular or axillary lymphadenopathy. Small left breast calcification.

ABDOMEN:

LIVER: Minimal focal fatty infiltration adjacent to the ligamentum teres.

BILE DUCTS: normal caliber.

GALLBLADDER: Mildly distended. No significant wall thickening. No calcified gallstones.

PANCREAS: Mildly atrophic.

SPLEEN: within normal limits.

ADRENALS: within normal limits.

KIDNEYS: The right kidney is mildly malrotated. There are fairly stable small bilateral renal cysts of varying complexity. The largest complex cyst on the right arises from the upper pole measuring 1.5 x 1.5 cm on image #28 of series 2, previously measuring 1.5 x 1.5 cm. The largest left renal complex cyst arises from the upper pole measuring 1.4 x 1.3 cm on image #24, previously measuring 1.4 x 1.3 cm. Minimal nonspecific bilateral perinephric stranding. No

Pt Name: [REDACTED]
Rm/ Bed: [REDACTED]

MRN: [REDACTED]
Page 1 of 3

CT CHEST ABD PEL W (OS) Results Report

[page 21 of 21]
CT CHEST ABD PEL W (OS) Results Report

Pt Name: [REDACTED]
Pt ID: [REDACTED]
DOB: [REDACTED]
Adm DTime: [REDACTED] +3926
Nurs Sta: [REDACTED]
Dx: [REDACTED]
Alerg: No Known Drug Allergies

MRN: [REDACTED]
Acct No: [REDACTED]
Age/Sex: 79Y/F
Attn Dr: [REDACTED]
Rm & Bed: [REDACTED]

Order Name: [REDACTED]
Result Name: CT CHEST ABD PEL W (OS)

Observation Dtime: [REDACTED] +3913
Result Status: Final Result

hydronephrosis.

PELVIS:

REPRODUCTIVE ORGANS: Grossly normal CT appearance of the uterus and adnexa.

URETERS: within normal limits.

BLADDER: within normal limits.

BOWEL: Normal caliber throughout. There has been a previous right hemicolectomy with reanastomosis. No evidence of local tumor recurrence. Small to moderate amount of stool is seen within the distal colon. No significant bowel wall thickening.

Diverticulosis coli without CT evidence of diverticulitis. No enlarged mesenteric lymph nodes.

PERITONEUM: no ascites or free air, no fluid collection.

VESSELS: Atherosclerotic changes.

RETROPERITONEUM: No enlarged retroperitoneal or pelvic nodes.

ABDOMINAL WALL: Anterior abdominal incision. Small fat-containing umbilical hernia. Small fat-containing left inguinal hernia. Tiny fat-containing right inguinal hernia.

BONES: Degenerative changes. Scattered tiny bone islands. Mild likely degenerative and chronic grade 1 anterolisthesis at the L4-L5 and L5-S1 levels.

IMPRESSION: 1. Areas of lung atelectasis. Findings consistent with prior granulomatous disease. No new lung nodule or mass.

2. Possible pulmonary hypertension.

3. Small fairly stable bilateral renal cysts of varying complexity.

Minimal nonspecific bilateral perinephric stranding. No hydronephrosis.

4. No evidence of local tumor recurrence status post right hemicolectomy.

5. Possible constipation.

6. Diverticulosis coli without CT evidence of diverticulitis.

7. Small umbilical and left inguinal hernias. Tiny right inguinal hernia.

8. Mild likely degenerative and chronic grade 1 anterolisthesis at the L4-L5 and L5-S1 levels.

CPT CODE:

Dictated By: [REDACTED] M.D. Electronically Signed: [REDACTED]

at: [REDACTED] +3913

Transcribed By: [REDACTED]

D: [REDACTED]

T: [REDACTED]

+3913

+3913

Comments

Result Comments:

Pt Name: [REDACTED]

Rm/ Bed: [REDACTED]

Page 2 of 3

CT CHEST ABD PEL W (OS) Results Report

Source: NCI Genomic Data Commons file 1c2fa8fb-211f-461d-9ecd-208c4539de5e (ER0060 ER-ABEO Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).